Surgical pathology report (de-identified scan), TCGA case TCGA-DJ-A3VF, project TCGA-THCA (Thyroid Carcinoma), tissue source site Memorial Sloan Kettering, specimen TCGA-DJ-A3VF-01A (Primary Tumor).

[page 1 of 3]
& Neck
And Neck

Date of Procedure:
Date of Receipt:
Date of Report:
Account #:
Billing Type:
Additional Copy to:

Clinical Diagnosis & History:

Thyroid isthmus nodule 1.2 cm FNA (+) papillary ca, bil. benign (on US) appearing nodules.

Specimens Submitted:

- 1: Left neck skin lesion
- 2: Pre-laryngeal level six lymph node
- 3: Total thyroidectomy
- 4: Left neck contents, level three and four

DIAGNOSIS:

1. Skin, left neck lesion; excision:
- Intradermal nevus

ICD-O-3
carcinoma, papillary, tall cell
8344/3

2. Pre-laryngeal level six lymph node:
Part # 2
Lymph Node Dissection:

Site: thyroid, NOS

C73.9

5-2-12
120

Metastatic papillary thyroid carcinoma
Number of lymph nodes examined: 2
Number of lymph nodes with metastatic disease: 2
Size of the largest lymph node involved by tumor: 0.5cm.
Size of the largest metastatic focus : 0.5 cm.
Extranodal extension is identified

3. Total thyroidectomy:

Part # 3

Tumor Type:

Papillary carcinoma, tall cell variant $\geq 50\%$ Tall cell variant per TSS /lw

Mitotic Activity:

Not identified

Tumor Necrosis:

Not identified

Other Tumor Features:

Marked stromal reaction

Tumor Location:

Right lobe

Tumor Size:

Greatest diameter is 1.0 cm.

Tumor Encapsulation:

None Identified

[page 2 of 3]
Blood Vessel Invasion:
Not identified

Extrathyroid Extension:
Invades: perithyroidal fibroadipose tissue

Surgical Margins:
Free of tumor

Tumor Multicentricity:
Microscopic foci present
Papillary microcarcinoma, 0.6 mm in greatest dimension (left lobe)

Adenoma(s) (away from the carcinoma):
Not Identified

Non-Neoplastic Thyroid:
Exhibits nodular hyperplasia

Parathyroid Glands:
Not Identified

4. Left neck contents, level three and four:

Part # 4

Lymph Node Dissection:

Metastatic papillary thyroid carcinoma
Number of lymph nodes examined: 10
Number of lymph nodes with metastatic disease: 2
Size of the largest lymph node involved by tumor: 0.6cm.
Size of the largest metastatic focus : 0.6 cm.
Extranodal extension is identified

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

*** Report Electronically Signed Out ***

Gross Description:

1). The specimen is received in formalin, labeled "Left neck skin lesion" and consists of a 0.8 x 0.4 cm, rubbery piece of tan skin tissue. Cut sections reveal a white tan focally calcified cut surface. Entirely submitted.

Summary of sections:
U - undesignated

2). The specimen is received in formalin, labeled "Pre laryngeal level six lymph node" and consists of a single yellow tan firm lymph node measuring 1.5 x 0.9 x 0.3 cm. The lymph node is entirely submitted.

Summary of sections:
LN - lymph node

[page 3 of 3]
3. The specimen is received fresh, labeled "total thyroid", and consists of a thyroid weighing 18 g. The right lobe measures 4.6 x 3.0 x 1.3 cm, the left lobe measures 4.0 x 2.5 x 1.3 cm and the isthmus measures 1.3 x 0.7 x 0.7 cm. The external surface is covered by a thin fibrous capsule. The posterior surface of the specimen is inked black, and the anterior is inked blue. Sectioning reveals a soft tan circumscribed nodule. The nodule is located in the upper pole of the right lobe, measures 1.0 x 0.8 x 0.7 cm, displays tan-brown cut surfaces, and is encapsulated. Sections through the remaining tissue reveal unremarkable parenchyma, which is red brown and beefy. Representative sections of the specimen are submitted for ... The remaining tissue is serially sectioned and entirely submitted.

Summary of sections:

RL - right lobe including the nodule, from superior to inferior

LL - left lobe, from superior to inferior

IS - Isthmus

4. The specimen is received fresh, labeled "left neck contents, level 3 and 4", and consists of multiple pink tan soft lymph nodes ranging from 0.3 to 1.0 cm in greatest dimension. All identified lymph nodes are submitted.

Summary of sections:

BLN - bisected lymph nodes

LN - lymph nodes

Summary of Sections:

Part 1: Left neck skin lesion

Block	Sect. Site	PCs
3	U	3

Part 2: Pre-laryngeal level six lymph node

Block	Sect. Site	PCs
1	LN	1

Part 3: Total thyroidectomy

Block	Sect. Site	PCs
2	IS	4
6	LL	8
10	RL	10

Part 4: Left neck contents, level three and four

Block	Sect. Site	PCs
2	bln	4
2	ln	6

Source: NCI Genomic Data Commons file 6d50384f-c66f-42f2-8bf7-ed4453901aca (TCGA-DJ-A3VF.8E171469-48B5-4A71-A2B0-72F743711E36.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).